Somatic mutation profile of tumor specimen TCGA-G7-A8LD-01A (aliquot TCGA-G7-A8LD-01A-11D-A35Z-10) from TCGA case TCGA-G7-A8LD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.1 years (25,977 days).
Specimen TCGA-G7-A8LD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8279e664-bd33-4e09-a819-9629b6c71d40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-A8LD-10A (Blood Derived Normal), aliquot TCGA-G7-A8LD-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d07ab391-f155-4870-a506-1c245faa28a7

The open-access MAF lists 45 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 32, Silent 8, Frame Shift Del 2, In Frame Del 1, Nonstop Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMNA | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs58436778, CM002044, COSV100738899; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CD93 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs139005135; called by muse, mutect2, varscan2
- CNTNAP5 | c.1880A>T p.K627M | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101444355; called by muse, mutect2
- COPB2 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1179755010, COSV60812792, COSV60813715; called by muse, mutect2, varscan2
- DMKN | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100304022; called by muse, mutect2, varscan2
- DPP6 | c.1591G>T p.D531Y (on ENST00000377770 / NM_001364500.2; = p.D469Y on NM_001936.5) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV100128676; called by muse, mutect2, varscan2
- DPY19L1 | c.1604A>G p.Q535R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100205126; called by muse, mutect2, varscan2
- FGF4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763955342, COSV51450476; called by muse, mutect2, varscan2
- FSTL4 | c.1345A>C p.S449R | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99534029; called by muse, mutect2, varscan2
- HACL1 | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 191/453 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337427; called by muse, mutect2, varscan2
- KCNJ12 | c.137T>A p.F46Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); catalogued as COSV100056367; called by muse, mutect2
- KIF5C | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101276223, COSV68480694; called by muse, mutect2, varscan2
- LRRN4 | c.762C>A p.N254K | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV101125477, COSV101125543; called by muse, mutect2, varscan2
- MAMDC2 | c.635G>C p.S212T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV101015938; called by muse, mutect2, varscan2
- MUC17 | c.4523C>T p.T1508M | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs374713003; called by muse, mutect2, varscan2
- NCKAP5 | c.3580A>G p.K1194E | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100494730; called by muse, mutect2, varscan2
- NCL | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100502503; called by muse, mutect2, varscan2
- NLRP4 | c.2663T>C p.L888P | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100017362; called by muse, mutect2, varscan2
- NPTX2 | c.1294T>C p.*432Qext*21 | Nonstop Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV99675142; called by muse, mutect2, varscan2
- OBSCN | c.22088C>G p.A7363G | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs1322238176, COSV100806310; called by muse, mutect2, varscan2
- PARD3 | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100402224; called by muse, varscan2
- PCDHA9 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.16); catalogued as COSV65326372; called by muse, mutect2, varscan2
- PCNT | c.5621A>G p.N1874S | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs752328874, COSV100856149; called by muse, mutect2, varscan2
- PRMT1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101212374; called by muse, mutect2, varscan2
- R3HDM1 | c.1386A>T p.Q462H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV99926968; called by muse, mutect2, varscan2
- SERAC1 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100894910; called by muse, mutect2, varscan2
- SIM2 | c.1106T>C p.L369S | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV99293721; called by muse, mutect2, varscan2
- SMARCA1 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 189/209 reads (90%) | catalogued as COSV64413328; called by muse, mutect2, varscan2
- SPHKAP | c.4874G>A p.R1625Q (on ENST00000392056 / NM_001142644.2; = p.R1596Q on NM_030623.3) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749321237, COSV60868729; called by muse, mutect2, varscan2
- XPR1 | c.1784T>G p.V595G | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV100851536; called by muse, mutect2, varscan2
- ZNF184 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV99280154; called by muse, mutect2, varscan2
- ZNF713 | c.1265G>A p.R422H (on ENST00000633730 / NM_001366796.2; = p.R435H on NM_182633.3) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs371670199; called by muse, mutect2, varscan2
- ZNF816 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99554743; called by muse, mutect2
- ANK2 | c.3763_3778del p.A1255Yfs*5 | Frame Shift Del (DEL) | VAF 57/77 reads (74%) | called by mutect2, pindel, varscan2
- ASAH2 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 150/355 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BAP1 | c.1452del p.S485Hfs*86 | Frame Shift Del (DEL) | VAF 31/49 reads (63%) | called by mutect2, pindel, varscan2
- CFAP36 | c.983_1024del p.R328_N341del | In Frame Del (DEL) | VAF 173/634 reads (27%) | called by mutect2, pindel
- AVPR1A | c.204C>G p.G68= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV100146924; called by muse, mutect2, varscan2
- CBY2 | c.363G>A p.V121= | Silent (SNP) | VAF 59/71 reads (83%) | catalogued as rs1409172162, COSV100137889; called by muse, mutect2, varscan2
- NOL8 | c.1242T>C p.N414= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as rs745703924, COSV100694715; called by muse, mutect2, varscan2
- PER2 | c.2163G>A p.K721= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV99612709; called by muse, mutect2, varscan2
- PLCD4 | c.843C>T p.F281= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs1422523071, COSV68842705; called by muse, mutect2, varscan2
- TBC1D31 | c.736A>C p.R246= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV99783313; called by muse, mutect2, varscan2
- TBX4 | c.96C>T p.P32= | Silent (SNP) | VAF 20/590 reads (3%) | catalogued as COSV99540768; called by muse, mutect2
- USP34 | c.4371G>A p.E1457= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV101277283; called by muse, mutect2
